Gene-level copy-number profile of tumor specimen TCGA-A5-A1OG-01A from TCGA case TCGA-A5-A1OG, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G3; Age at diagnosis: 65.6 years (23,956 days).
Specimen TCGA-A5-A1OG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.3e66c95e-de64-48ca-9e71-a619e7312102.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A5-A1OG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/287ca16d-39d3-4106-8027-f417e56ff13f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 58; copy number 2: 8,140; copy number 3: 21,683; copy number 4: 19,992; copy number 5: 3,395; copy number 6: 3,666; copy number 7: 1,443; copy number 8: 1,275; copy number 9: 26; copy number 10: 131.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A5-A1OG-01A-11D-A14F-01): tumor purity 0.59, ploidy 3.67, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,064,089–181,265,145, 3 genes: LINC00290, AC019235.1, LINC02500.
- chr7:110,108,031–110,534,757, 1 gene (within-gene range 0–1): AC073114.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,875 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:98,997,261–99,490,035, 14 genes, copy number 7: TSGA10, SMC3P1, AC079447.1, C2orf15, LIPT1, AC092587.1, MITD1, MRPL30, LYG2, LYG1, TXNDC9, EIF5B, REV1, AC018690.1.
- chr2:101,962,056–102,452,565, 14 genes, copy number 7: LINC01127, IL1R2, AC007271.1, IL1R1, IL1R1-AS1, IL1RL2, FAM183DP, IL1RL1, IL18R1, SDR42E1P5, IL18RAP, MIR4772, AC007278.2, AC007278.1.
- chr2:112,346,011–117,539,464, 86 genes, copy number 7 (broad region; genes not listed).
- chr2:139,323,921–140,221,485, 12 genes, copy number 7: AC013265.1, AC062021.1, AC016710.1, SNORA72, MRPS18BP2, RPL9P13, AC078851.1, RN7SL283P, LINC01853, MTCO1P44, MTND2P19, MTND1P27.
- chr2:140,234,737–140,683,888, 3 genes, copy number 7: AC092156.1, MIR7157, COPRSP1.
- chr2:141,167,257–141,208,376, 2 genes, copy number 7: RNU6-904P, RPS16P3.
- chr3:106,848,671–106,902,523, 11 genes, copy number 7: FCF1P3, MTND4P16, MTND4LP3, MTND3P6, MTCO3P35, MTATP6P22, MTND5P16, MTND6P6, MTCO1P35, MTND1P16, MTND2P14.
- chr8:127,686,343–129,683,770, 22 genes, copy number 10 (within-gene range 6–10): CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686.
- chr12:5,531,869–5,946,232, 1 gene, copy number 7 (within-gene range 5–7): ANO2.
- chr12:5,948,877–6,538,374, 27 genes, copy number 7: VWF, RN7SL69P, AC005845.1, CD9, Y_RNA, ATP5MFP5, PLEKHG6, TNFRSF1A, RN7SL391P, SCNN1A, LTBR, AC005840.2, AC005840.1, SRP14P1, CD27-AS1, CD27, TAPBPL, VAMP1, AC005840.4, AC005840.3, MRPL51, NCAPD2, SCARNA10, AC006064.5, AC006064.3, GAPDH, AC006064.4.
- chr12:47,237,734–48,442,411, 61 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr16:24,333,415–35,912,516, 555 genes, copy number 7–9 (broad region; genes not listed).
- chr19:19,856,975–58,605,223, 1,883 genes, copy number 7–10 (broad region; genes not listed).
- chr20:30,377,372–33,401,561, 96 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr20:44,496,221–46,171,237, 88 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 58. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
